TCGA case TCGA-31-1944 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Imperial College. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6fee41dc-b8a9-4347-8085-b7e05f813ad0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 47.1 years (17,207 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 1,386 days (3.8 years).
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: No macroscopic disease; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 126 days; Number of cycles: 6; Treatment dose: 4,200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 126 days; Number of cycles: 6; Treatment dose: 1,650 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 153 days; Days to treatment end: 223 days; Number of cycles: 3; Treatment dose: 345 mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 153 days; Days to treatment end: 223 days; Number of cycles: 3; Treatment dose: 835 mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Recurrent Disease; Days to treatment start: 479 days (1.3 years); Days to treatment end: 944 days (2.6 years); Treatment dose: 9,140 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 721 days (2.0 years); Days to treatment end: 841 days (2.3 years); Number of cycles: 6; Treatment dose: 3,300 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 721 days (2.0 years); Days to treatment end: 841 days (2.3 years); Number of cycles: 6; Treatment dose: 1,650 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Megestrol Acetate; Days to treatment start: 944 days (2.6 years); Days to treatment end: 1,099 days (3.0 years); Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Olaparib; Initial disease status: Progressive Disease; Days to treatment start: 1,032 days (2.8 years); Treatment outcome: Treatment Ongoing; Route of administration: Oral.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 49.0 years (17,885 days); Days to diagnosis: 678 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 701 days (1.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 678 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 678 days (1.9 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,386 days (3.8 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-31-1944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.5; Shortest dimension: 0.3.
  Slide TCGA-31-1944-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 27.
  Slide TCGA-31-1944-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-31-1944-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Megace; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Switched from Tamozifen.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3, Route of administrations: Route of administration: IP.
- Drug treatment 4: Pharmaceutical therapy drug name: AZD 2281; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Paciltaxel; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,386 days; disease-specific survival: no event (censored), 1,386 days; disease-free interval: event (new tumor event after initially disease-free), 678 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 678 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-31-1944-01): tumor purity 0.79, ploidy 1.93, whole-genome doublings 0 (call status: legacy_call).
